Gene-level copy-number profile of tumor specimen TCGA-2A-A8VO-01A from TCGA case TCGA-2A-A8VO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.4 years (20,958 days).
Specimen TCGA-2A-A8VO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ec1c19d3-4d62-452a-ae7a-37b0411d7045.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2A-A8VO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e6345da-cb21-4168-a710-8c75c6b3db6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,854; copy number 2: 55,961; copy number 5: 1; copy number 7: 1; copy number 9: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2A-A8VO-01A-11D-A376-01): tumor purity 0.55, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:46,129,989–46,146,688, 1 gene, copy number 9: ENPP4.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 9: AC139365.2, AC139365.1.
- chr11:50,409,042–50,422,316, 1 gene, copy number 7: AC024405.1.

Autosomal genes at a single copy (total copy number 1): 1,468. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
